Somatic mutation profile of tumor specimen 0DMN26 from CCDI case PBCASH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Myofibroblastic tumor, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 9.0 years (3,285 days).
Specimen 0DMN26: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22c453a2-f864-4491-aafd-d3d8445265cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMN1D (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb3fb06f-cfdf-4e4d-b62e-5222e004ee73

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Nonsense Mutation 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLG1 | c.2573G>T p.R858L | Missense Mutation (SNP) | VAF 74/1186 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.339); catalogued as rs201998866; called by muse, mutect2
- MROH9 | c.2362C>T p.R788* | Nonsense Mutation (SNP) | VAF 60/676 reads (9%) | catalogued as rs1447165676; called by muse, mutect2
- CEBPB | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KIF1C | c.2808_2809del p.G937Sfs*70 | Frame Shift Del (DEL) | VAF 13/122 reads (11%) | called by mutect2, varscan2
- MPHOSPH10 | c.1739A>C p.K580T | Missense Mutation (SNP) | VAF 98/1120 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2
- PCDHA11 | c.1782C>T p.R594= | Silent (SNP) | VAF 39/316 reads (12%) | catalogued as rs782085408, COSV100252132; called by muse, mutect2, varscan2
- RIN2 | c.366G>A p.R122= (on ENST00000255006 / NM_001242581.1; = p.R73= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/642 reads (5%) | catalogued as rs1438592923; called by muse, mutect2
- ABI2 | c.*50A>G | 3'UTR (SNP) | VAF 20/175 reads (11%) | called by muse, mutect2, varscan2
